Somatic mutation profile of tumor specimen HCM-STAN-0848-C20-01A (aliquot HCM-STAN-0848-C20-01A-11D-A882-36) from HCMI case HCM-STAN-0848-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2.
Specimen HCM-STAN-0848-C20-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0964c18-ebc6-4012-899c-96db12c4b103.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-0848-C20-11A (Solid Tissue Normal), aliquot HCM-STAN-0848-C20-11A-11D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d8a5776-a78a-422a-a7c6-0cf506c90f1e

The open-access MAF lists 110 somatic variants for this specimen: 82 protein-altering or splice-affecting, 25 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 25, Frame Shift Del 5, Nonsense Mutation 5, Frame Shift Ins 2, In Frame Del 1, 5'Flank 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.4200del p.I1401Sfs*47 | Frame Shift Del (DEL) | VAF 30/296 reads (10%) | catalogued as rs398123786, CM053841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 97/300 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 128/254 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- AMER3 | c.2347del p.E783Sfs*35 | Frame Shift Del (DEL) | VAF 49/451 reads (11%) | catalogued as COSV58470026; called by mutect2, pindel, varscan2
- ARHGAP31 | c.3127G>A p.G1043R | Missense Mutation (SNP) | VAF 115/532 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs1263839755; called by muse, mutect2, varscan2
- ASB4 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 94/270 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as COSV57508202; called by muse, mutect2, varscan2
- BDP1 | c.5497C>G p.H1833D | Missense Mutation (SNP) | VAF 108/565 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV62435071; called by muse, mutect2, varscan2
- C16orf71 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 57/387 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs781592659; called by muse, mutect2, varscan2
- CIAO3 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 144/400 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs752289658; called by muse, varscan2
- ERBB2 | c.2632C>T p.H878Y | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54066178; called by muse, mutect2, varscan2
- FANCL | c.503A>G p.D168G | Missense Mutation (SNP) | VAF 80/286 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV52074779; called by muse, mutect2, varscan2
- FSIP2 | c.17248G>A p.E5750K | Missense Mutation (SNP) | VAF 74/260 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1353615587, COSV58077311; called by muse, mutect2
- LRCH2 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 123/154 reads (80%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs1027988478, COSV57747256; called by muse, mutect2, varscan2
- LYPD3 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 40/358 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as rs745685365, COSV54987883; called by muse, mutect2, varscan2
- MIPEP | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 89/646 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs546719717, COSV66301531; called by muse, mutect2, varscan2
- MTOR | c.1499A>T p.D500V | Missense Mutation (SNP) | VAF 129/335 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV63872465; called by muse, mutect2, varscan2
- MYO18B | c.5684G>A p.R1895H | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs370592345, COSV100125144; called by muse, mutect2, varscan2
- NEUROD1 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 39/309 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV54549079; called by muse, mutect2, varscan2
- NEUROD4 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs760713144; called by muse, mutect2, varscan2
- OR1N1 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 178/345 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs767738634, COSV59196059; called by muse, mutect2, varscan2
- OR2V1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 65/446 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs762779171, COSV61459392; called by muse, mutect2, varscan2
- PKHD1 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 113/382 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs186202437; called by muse, mutect2, varscan2
- PLCL2 | c.2422G>A p.A808T (on ENST00000615277 / NM_001144382.2; = p.A682T on NM_015184.5) | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs148180373; called by muse, mutect2, varscan2
- RGS12 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 136/399 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359287871; called by muse, mutect2, varscan2
- ROR2 | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 89/383 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs980417569; called by muse, mutect2, varscan2
- RPL3L | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 122/446 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs370640499; called by muse, varscan2
- SHOC2 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV54624190; called by muse, mutect2, varscan2
- SLC5A4 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 65/213 reads (31%) | catalogued as rs754133867, COSV56670664; called by muse, mutect2, varscan2
- SULT2A1 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 92/338 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs529798485; called by muse, mutect2, varscan2
- TIE1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 69/563 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs746300033; called by muse, mutect2, varscan2
- TOPAZ1 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs376633336; called by muse, mutect2, varscan2
- TTC28 | c.2821G>C p.E941Q | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV67418093; called by muse, mutect2
- USH2A | c.2072G>T p.C691F | Missense Mutation (SNP) | VAF 109/354 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM095918; called by muse, mutect2, varscan2
- VN1R1 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.155); catalogued as COSV100320601; called by muse, mutect2, varscan2
- WASF3 | c.1450G>A p.V484M | Missense Mutation (SNP) | VAF 108/666 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1179470680, COSV58967219; called by muse, mutect2, varscan2
- WDFY3 | c.7156C>T p.R2386* | Nonsense Mutation (SNP) | VAF 87/347 reads (25%) | catalogued as rs989023195, COSV99883382; called by muse, mutect2, varscan2
- ZNF142 | c.4387G>A p.D1463N (on ENST00000411696 / NM_001379660.1; = p.D1263N on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs755179850; called by muse, mutect2, varscan2
- ZNF596 | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV100261862; called by muse, mutect2, varscan2
- ACAD10 | c.1455A>T p.E485D | Missense Mutation (SNP) | VAF 121/374 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- ADGRG5 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AKT3 | c.62A>G p.N21S | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ANK2 | c.2734_2754del p.H912_D918del | In Frame Del (DEL) | VAF 40/323 reads (12%) | called by mutect2, pindel
- BORA | c.1153G>C p.G385R (on ENST00000613797; = p.G310R on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/477 reads (30%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BPTF | c.4340C>T p.T1447I | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BTBD18 | c.1834C>T p.H612Y | Missense Mutation (SNP) | VAF 97/315 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTNL3 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 224/452 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- CFAP46 | c.1939C>A p.P647T | Missense Mutation (SNP) | VAF 120/391 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by mutect2, varscan2
- CLP1 | c.442G>T p.V148L | Missense Mutation (SNP) | VAF 128/422 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DEFB124 | c.106A>C p.T36P | Missense Mutation (SNP) | VAF 70/495 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNAJC13 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 38/529 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.931); called by muse, mutect2
- DNER | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 39/292 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by mutect2, varscan2
- EHBP1L1 | c.3938G>C p.G1313A | Missense Mutation (SNP) | VAF 53/344 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ENPP1 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- EXPH5 | c.2420C>T p.T807I | Missense Mutation (SNP) | VAF 81/318 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- FDCSP | c.126dup p.V43Cfs*23 | Frame Shift Ins (INS) | VAF 39/325 reads (12%) | called by mutect2, pindel, varscan2
- FKBP7 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FRMPD1 | c.3274G>C p.G1092R | Missense Mutation (SNP) | VAF 82/395 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- HAUS2 | c.530T>A p.V177E | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.122); called by mutect2, varscan2
- HPS1 | c.735C>G p.Y245* | Nonsense Mutation (SNP) | VAF 35/232 reads (15%) | called by muse, mutect2, varscan2
- IFT88 | c.2389T>A p.Y797N (on ENST00000319980 / NM_001318493.2; = p.Y788N on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 137/439 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KRTAP15-1 | c.292G>C p.G98R | Missense Mutation (SNP) | VAF 144/400 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- LRRC72 | c.568A>T p.K190* | Nonsense Mutation (SNP) | VAF 74/242 reads (31%) | called by muse, mutect2, varscan2
- MBD5 | c.786T>A p.N262K | Missense Mutation (SNP) | VAF 109/271 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- MED16 | c.1610C>A p.S537* | Nonsense Mutation (SNP) | VAF 78/406 reads (19%) | called by muse, mutect2, varscan2
- MFSD14B | c.219_220insG p.F74Vfs*32 | Frame Shift Ins (INS) | VAF 71/310 reads (23%) | called by mutect2, pindel, varscan2
- MGAM2 | c.2462T>G p.L821R | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MMAA | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 71/371 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- NCOA2 | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 109/321 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEUROD4 | c.149A>T p.E50V | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NUMA1 | c.1691del p.E564Gfs*4 | Frame Shift Del (DEL) | VAF 61/417 reads (15%) | called by mutect2, pindel, varscan2
- OR8H1 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); called by mutect2, varscan2
- OSBPL7 | c.1133_1137delinsC p.Y378Sfs*99 | Frame Shift Del (DEL) | VAF 39/320 reads (12%) | called by pindel, varscan2*
- OTUD7A | c.2530G>A p.A844T (on ENST00000307050 / NM_001382637.1; = p.A837T on NM_130901.3) | Missense Mutation (SNP) | VAF 116/253 reads (46%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.024); called by muse, varscan2
- PLCG1 | c.1119T>G p.D373E | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.533); called by muse, mutect2
- PRKCZ | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 113/344 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RANBP2 | c.2025A>C p.K675N | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, varscan2
- RBMS2 | c.574A>C p.I192L | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- SSC5D | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 68/346 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STRA8 | c.650C>T p.P217L (on ENST00000275764; = p.P195L on NM_182489.2) | Missense Mutation (SNP) | VAF 138/497 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYNE1 | c.21243del p.I7081Mfs*8 (on ENST00000367255 / NM_182961.4; = p.I7010Mfs*8 on NM_033071.3) | Frame Shift Del (DEL) | VAF 50/217 reads (23%) | called by mutect2, pindel, varscan2
- TRAF6 | c.1240A>G p.M414V | Missense Mutation (SNP) | VAF 86/288 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- ZNF18 | c.691A>C p.T231P | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- APCDD1L | c.1011C>T p.T337= | Silent (SNP) | VAF 22/738 reads (3%) | catalogued as rs1568731975, COSV64487714; called by muse, mutect2
- ATP1A3 | c.669C>T p.G223= (on ENST00000545399 / NM_001256214.2; = p.G210= on NM_152296.5) | Silent (SNP) | VAF 59/205 reads (29%) | catalogued as rs199906040; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA1S | c.639C>T p.I213= | Silent (SNP) | VAF 82/256 reads (32%) | catalogued as rs1229722414, COSV62938408; ClinVar: likely benign; called by muse, mutect2, varscan2
- CD40 | c.336G>A p.T112= | Silent (SNP) | VAF 42/410 reads (10%) | catalogued as rs267605960, COSV64847508; called by muse, mutect2, varscan2
- CHRNA7 | c.129C>G p.P43= | Silent (SNP) | VAF 15/383 reads (4%) | catalogued as rs769072651; called by muse, mutect2
- CRAMP1 | c.981G>A p.P327= | Silent (SNP) | VAF 117/378 reads (31%) | catalogued as rs778796282; called by muse, mutect2, varscan2
- CSMD1 | c.8193G>A p.T2731= (on ENST00000520002; = p.T2730= on NM_033225.6) | Silent (SNP) | VAF 66/141 reads (47%) | catalogued as rs757939119, COSV59377764; called by muse, mutect2, varscan2
- CTSE | c.243T>G p.T81= | Silent (SNP) | VAF 79/231 reads (34%) | called by muse, mutect2, varscan2
- CYLD | c.1881G>A p.K627= | Silent (SNP) | VAF 62/218 reads (28%) | called by muse, varscan2
- DNAH1 | c.4944G>A p.Q1648= | Silent (SNP) | VAF 90/311 reads (29%) | catalogued as rs1187570116; called by muse, mutect2, varscan2
- DNAH5 | c.2868C>T p.R956= | Silent (SNP) | VAF 197/410 reads (48%) | catalogued as rs767246326, COSV54204914; called by muse, mutect2, varscan2
- EIF2A | c.510T>C p.I170= | Silent (SNP) | VAF 77/335 reads (23%) | called by muse, mutect2, varscan2
- EZH2 | c.1131T>C p.D377= (on ENST00000460911 / NM_001203247.2; = p.D382= on NM_004456.5) | Silent (SNP) | VAF 22/479 reads (5%) | catalogued as COSV100235434; called by muse, mutect2
- FLT1 | c.2610C>T p.S870= | Silent (SNP) | VAF 102/546 reads (19%) | called by muse, mutect2, varscan2
- FLT4 | c.3474G>A p.A1158= | Silent (SNP) | VAF 251/514 reads (49%) | catalogued as rs887043029; called by muse, varscan2
- GALNT9 | c.942C>T p.D314= | Silent (SNP) | VAF 90/340 reads (26%) | catalogued as rs782318389, COSV61100613; called by muse, mutect2, varscan2
- HOXA4 | c.846A>T p.R282= | Silent (SNP) | VAF 42/325 reads (13%) | called by muse, mutect2, varscan2
- HTR1B | c.276G>C p.A92= | Silent (SNP) | VAF 120/388 reads (31%) | called by muse, mutect2, varscan2
- HYOU1 | c.2892C>T p.S964= | Silent (SNP) | VAF 27/300 reads (9%) | catalogued as rs782811813, COSV68215742; called by muse, mutect2
- KCNJ3 | c.987T>C p.P329= | Silent (SNP) | VAF 29/271 reads (11%) | called by muse, mutect2, varscan2
- MBD3L2 | c.456G>A p.G152= | Silent (SNP) | VAF 26/163 reads (16%) | catalogued as rs1322149274; called by mutect2, varscan2
- NLGN4Y | c.2247C>T p.H749= | Silent (SNP) | VAF 235/312 reads (75%) | called by muse, mutect2, varscan2
- NPHS1 | c.117A>G p.E39= | Silent (SNP) | VAF 146/384 reads (38%) | called by muse, mutect2, varscan2
- PCDHB13 | c.1665C>T p.N555= | Silent (SNP) | VAF 207/909 reads (23%) | catalogued as rs377408073; called by muse, mutect2, varscan2
- ZPBP2 | c.498G>A p.V166= (on ENST00000348931 / NM_199321.3; = p.V144= on NM_198844.3) | Silent (SNP) | VAF 62/371 reads (17%) | catalogued as rs751383469, COSV62375656; called by muse, mutect2
- AC244258.1 | n.461C>A | RNA (SNP) | VAF 32/130 reads (25%) | called by mutect2, varscan2
- ARNTL | c.180-73_180-66del | Intron (DEL) | VAF 47/347 reads (14%) | called by mutect2, pindel, varscan2
- G3BP1 | chr5:151770525 G>A | 5'Flank (SNP) | VAF 173/704 reads (25%) | called by muse, mutect2, varscan2
